Gene-level copy-number profile of tumor specimen TCGA-NF-A4WX-01A from TCGA case TCGA-NF-A4WX, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IV; Age at diagnosis: 61.3 years (22,407 days).
Specimen TCGA-NF-A4WX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.507c2d17-c344-4c80-993f-566f1d6a978b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-NF-A4WX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/56bc18bd-d8ee-4eb8-baf3-61c5a9726a81

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 3,260; copy number 2: 2,011; copy number 3: 5,535; copy number 4: 26,733; copy number 5: 7,591; copy number 6: 10,427; copy number 7: 3,816; copy number 8: 154; copy number 9: 109; copy number 10: 54; copy number 11: 9; copy number 13: 60; copy number 14: 8; copy number 22: 38.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-NF-A4WX-01A-11D-A28Q-01): tumor purity 0.9, ploidy 5.83, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:89,948,697–90,222,851, 15 genes: DEF8, CENPBD1, AFG3L1P, DBNDD1, GAS8, GAS8-AS1, URAHP, PRDM7, TUBB8P7, FAM157C, AC133919.1, AC133919.2, RNU6-355P, LINC02193, CICP25.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 278 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:168,317,497–169,103,276, 17 genes, copy number 9 (within-gene range 6–9): AL022100.1, MIR557, AL023755.1, AL022100.2, QRSL1P1, XCL2, AL031736.1, XCL1, AL031736.2, DPT, AL135926.1, AL031275.1, LINC00626, SUMO1P2, AL135926.2, LINC00970, RPL29P7.
- chr2:67,562,067–68,320,051, 15 genes, copy number 10 (within-gene range 5–10): LINC02831, AC007422.1, AC010987.1, LINC01812, FBXL12P1, C1D, AC017083.4, WDR92, PPIAP64, AC017083.3, PNO1, PPP3R1, AC017083.2, AC017083.1, CNRIP1.
- chr3:168,858,659–169,038,416, 5 genes, copy number 11: RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997.
- chr5:36,246,913–36,725,195, 8 genes, copy number 14 (within-gene range 6–14): RANBP3L, AC114277.1, RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3.
- chr7:20,096,137–23,897,335, 69 genes, copy number 9–22 (broad region; genes not listed).
- chr8:21,690,398–22,006,585, 4 genes, copy number 11 (within-gene range 6–11): GFRA2, OR6R2P, DOK2, XPO7.
- chr8:29,048,494–29,360,222, 9 genes, copy number 10: RNA5SP260, AC108449.2, KIF13B, AC108449.3, AC108449.1, HMGB1P23, DUSP4, AC084262.2, AC084262.1.
- chr8:94,487,689–94,713,812, 12 genes, copy number 9: VIRMA, AC023632.5, AC023632.2, AC023632.1, AC023632.3, AC023632.4, AC108860.2, ESRP1, Metazoa_SRP, AC108860.1, AP005660.1, Y_RNA.
- chr8:127,578,473–128,564,679, 18 genes, copy number 13: AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824.
- chr12:13,437,942–13,982,002, 1 gene, copy number 9 (within-gene range 7–9): GRIN2B.
- chr12:14,169,746–20,136,163, 90 genes, copy number 9–13 (broad region; genes not listed).
- chr13:23,465,776–23,970,188, 9 genes, copy number 10: LINC00327, LINC00352, TNFRSF19, MIPEP, MTCO3P2, PCOTH, C1QTNF9B, ANKRD20A19P, AL445985.2.
- chr20:34,088,309–34,560,345, 21 genes, copy number 10 (within-gene range 6–10): EIF2S2, RPS2P1, AL031668.2, ASIP, XPOTP1, AL035458.2, AL035458.1, AHCY, AL356299.2, AL356299.1, ITCH, Y_RNA, CDC42P1, ITCH-AS1, ITCH-IT1, MIR644A, FDX1P1, AL109923.1, DYNLRB1, Y_RNA, MAP1LC3A.

Autosomal genes at a single copy (total copy number 1): 839. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
